Gene-level copy-number profile of specimen HCM-CSHL-0160-C18-85A from HCMI case HCM-CSHL-0160-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: GB; Age at diagnosis: 83.9 years (30,635 days).
Specimen HCM-CSHL-0160-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 53b5ef78-ac99-4661-b1b1-c912e0953fab.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0160-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,218 have no estimate.
https://portal.gdc.cancer.gov/files/8148f6c9-0b4e-4096-98d9-22fe7f6fa99e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 6; copy number 2: 39; copy number 3: 9,276; copy number 4: 27,520; copy number 5: 10,236; copy number 6: 4,453; copy number 7: 4,195; copy number 8: 2,577; copy number 9: 11; copy number 11: 92.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 103 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:128,533,652–130,791,724, 90 genes, copy number 11 (broad region; genes not listed).
- chr7:130,822,868–130,823,511, 2 genes, copy number 11: AC016831.2, H4P1.
- chr8:144,973,589–145,066,685, 7 genes, copy number 9: ZNF252P, AF235103.1, TMED10P1, ZNF252P-AS1, AF235103.2, AC139103.1, C8orf33.
- chr15:43,593,054–43,632,283, 4 genes, copy number 9 (within-gene range 8–9): CKMT1B, STRC, RNU6-554P, AC011330.3.

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
